Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A2I1, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A2I1-01A (Primary Tumor).

[page 1 of 4]
PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender: F

Ref. Physician:

Patient Address:

Location:

Service: Urology

Billing

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Type:

INPATIENT

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

High grade UCC with focal superficial lamina propria invasion and CIS status post TURBT and

Specimens Submitted:

- 1: SP: Lymph nodes, right distal pelvic; dissection
- 2: SP: Lymph nodes, left distal pelvic; dissection
- 3: SP: Bladder, uterus, anterior vaginal wall, bilateral tubes and ovaries and urethra; radical cystectomy and hysterectomy
- 4: SP: Distal left ureter
- 5: SP: Distal right ureter

DIAGNOSIS:

1. SP: Lymph nodes, right distal pelvic; dissection:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 21

ICD-O-3

Carcinoma, papillary urothelial, NOS
8130/3

Site: bladder, wall, NOS C67.9

hw 6/24/14

2. SP: Lymph nodes, left distal pelvic; dissection:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 9

3. SP: Bladder, uterus, anterior vaginal wall, bilateral tubes and ovaries and urethra; radical cystectomy and hysterectomy:

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Papillary and flat

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Identified

Bladder Local Invasion:

Deep half of muscularis propria

Extravesical Tumor Extension:

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Ureters involved by carcinoma in situ

Vascular Invasion:
Identified

Perineural Invasion:
Not identified

Surgical Margins:
Carcinoma in situ present at left ureteral margin. Section from right ureteral margin shows total denudation with rare, markedly atypical cells floating free in the lumen. For final ureteral margins, see also parts 4 and 5.

Non-Neoplastic Mucosa:
Exhibiting proliferative cystitis (Brunn's nests, cystitis cystica, cystitis glandularis)

Female Genital Organs:
The cervix shows chronic inflammation
The endometrium shows atrophy
Remaining genital organs are unremarkable

Perivesical Lymph Nodes:
Not identified

The Pathologic Stage is (AJCC 2002):
pT2b (Invades deep half of muscularis propria)

4. Ureter, left distal; segmental resection:
Benign segment of ureter

5. Ureter, right distal; segmental resection:
Benign segment of ureter

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result Spec
RECUT

al Stain

Comment

Gross Description:

1). The specimen is received fresh, labeled "Right distal pelvic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 1.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

BLN - two bisected lymph nodes

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

2). The specimen is received in formalin, labeled "Left distal pelvic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 0.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

BLN - bisected lymph node

BLN2 - two bisected lymph nodes

3. The specimen is received fresh, labeled "bladder, uterus, anterior marginal wall, bilateral tubes and ovaries and urethra*". It consists of a pelvic en-block resection comprising urinary bladder, uterus with adnexa, portion of vagina, and urethra. The bladder measures 8 x 7 x 4 cm, the uterus measures 8 x 4 x 3 cm, the right ovary measures 2 x 1.5 x 1 cm, the right fallopian tube measures 6 x 0.4 x 0.4 cm, the left ovary measures 2 x 1.2 x 1.2 cm, and the left fallopian tube measures 6.5 x 0.4 x 0.4 cm. The portion of vaginal cuff measures 7 x 2.2 cm. The distal urethra and the vaginal cuff margin are shaved and submitted. The ureteric stumps measure 1.5 cm. The specimen is inked as follows: right resection margin = black and left resection margin = blue and the bladder is opened anteriorly to reveal 2 masses. The larger mass occupies the right anterior wall and measures 2.2 x 2 x 0.8 cm, and the smaller is located on posterior wall and measures 0.9 x 0.8 x 0.6 cm. The remaining mucosa show diffuse granular appearance. The uterus is bivalved to reveal smooth and thin endometrium. The ovaries and fallopian tubes show no abnormalities. Tissue is submitted for TPS (solid mass #1, solid mass #2, diffuse granular mucosa). Representative sections are submitted.

Summary of sections:

UTHM - distal urethra

RUM - right ureter margin

LUM - left ureter margin

RAM - right anterior wall solid mass

PM - posterior wall solid mass

GM - granular mucosa

RUO - right ureteric orifice

LUO - left ureteric orifice

LP - left posterior wall

LA - left anterior wall

RP - right posterior wall

RA - right anterior wall

TRI - trigone

DOM - dome

EMM - endometrium

CX - cervix

DVM - distal vaginal margin

RTO - right tube and ovary

LTO - left tube and ovary

4). The specimen is received in formalin, labeled "Distal left ureter unclipped end is margin" and consists of a tubular segment of tan elastic tissue with attached small amount of unremarkable fat, measuring 4.5 cm in length and 0.4 cm in average diameter. There is a clip demarcating the opposite site as the margin. The specimen is serially submitted from the unclipped end to the opposite and entirely submitted.

Summary of sections:

UE - unclipped end

CE - clipped end

RT - remaining tissue

5). The specimen is received in formalin, labeled "Distal right ureter unclipped end is margin" and consists of a tubular segment of tan elastic tissue with attached small amount of unremarkable fat, measuring 4.6 cm in length and 0.4 cm in average diameter. There is a clip demarcating the opposite site as the margin. The specimen is serially submitted from the unclipped end to the opposite and entirely submitted.

Summary of sections:

UE - unclipped end

CE - clipped end

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

RT – remaining tissue

Summary of Sections:

Part 1: SP: Lymph nodes, right distal pelvic; dissection

Block	Sect. Site	PCs
3	BLN	12
3	LN	15

Part 2: SP: Lymph nodes, left distal pelvic, dissection

Block	Sect. Site	PCs
1	BLN	2
3	bln2	12
1	LN	2

Part 3: SP: Bladder, uterus, anterior vaginal wall, bilateral tubes and ovaries and urethra; radical cystectomy and hysterectomy

Block	Sect. Site	PCs
1	cx	1
1	dome	1
1	dvm	1
2	emm	2
4	gm	4
1	la	1
1	lp	1
1	lto	1
1	lum	1
1	luo	1
2	pm	2
1	ra	1
6	ram	6
1	rp	1
1	rto	1
1	rum	1
1	ruo	1
1	tri	1
1	uthm	1

Part 4: SP: Distal left ureter

Block	Sect. Site	PCs
1	CE	1
3	RT	9
1	UE	1

Part 5: SP: Distal right ureter

Block	Sect. Site	PCs
1	CE	1
3	RT	12
1	UE	1

Source: NCI Genomic Data Commons file 86bfffb7-b992-4582-ac21-e639c818a50d (TCGA-DK-A2I1.4E78ED88-FF1B-406C-98B8-A836D6AEA1E9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).